Somatic mutation profile of tumor specimen TCGA-VD-A8KA-01B (aliquot TCGA-VD-A8KA-01B-11D-A39W-08) from TCGA case TCGA-VD-A8KA, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 22.6 years (8,271 days).
Specimen TCGA-VD-A8KA-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2f12ce9-c160-4029-8d11-b7609a58e7c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KA-10A (Blood Derived Normal), aliquot TCGA-VD-A8KA-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a914b35b-b934-4208-b608-aa388b362732

The open-access MAF lists 11 somatic variants for this specimen: 11 protein-altering or splice-affecting.
By variant classification: Missense Mutation 11.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 30/54 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GBA2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs762730206, COSV62306157; called by muse, mutect2, varscan2
- LCE3D | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.339); catalogued as rs201921868, COSV64230604; called by muse, mutect2, varscan2
- OR5L2 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1489088383; called by muse, mutect2, varscan2
- SIK3 | c.2784C>A p.D928E (on ENST00000445177 / NM_001366686.2; = p.D886E on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.041); catalogued as rs746419435; called by muse, mutect2, varscan2
- EHD3 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 121/215 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- GLIS3 | c.93G>T p.M31I | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INPP5E | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PAG1 | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SELE | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
